Surgical pathology report (de-identified scan), TCGA case TCGA-49-6767, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Johns Hopkins, specimen TCGA-49-6767-01A (Primary Tumor).

[page 1 of 4]
[REDACTED]

Order Name:

Result Name:

Path Report

Observation Date-time:

Result Status:

[REDACTED]

[REDACTED]

[REDACTED]

FINAL PATHOLOGIC DIAGNOSIS

A.-J. Specimen type and procedures: Lung, right middle lobe
en block wedge resection right upper lobe, levels 10, 9, 11, 12, 13,
7, R4, R2, lymph node biopsies and partial pericardectomy;

Tumor site: Right middle lobe.

Tumor histologic type: Adenocarcinoma.

Tumor focality: Unifocal.

Histologic grade: Poorly differentiated.

Tumor dimension: 4.5 cm.

Pleural invasion: Not identified.

Direct tumor extension into extrapulmonary structures:

Adenocarcinoma in pericardium (see note).

Bronchial and vascular margins: Uninvolved by carcinoma.

Parenchymal (staple) margin: Involved by carcinoma.

Other tissue margins: Not applicable.

Lymphovascular invasion: Not identified.

Lymph nodes: Metastatic carcinoma not identified.

8 lymph nodes examined.

Staging: AJCC: pT3(based on pericardial involvement)N0.

Note: Given the carcinoma is present at the soft tissue
pulmonary wedge resection margin, it is favored that the carcinoma
involving the pericardium is by direct extension. Further clinical
correlation may be necessary in this regard.

***Electronically Signed Out By [REDACTED]

Date Reported: [REDACTED]

[REDACTED]

[REDACTED]

[page 2 of 4]
Order Name:

Result Name:

Path Report

Observation Date-time:

Result Status:

MACROSCOPIC DESCRIPTION

The specimens are submitted in ten containers.

2 of 4

A. The first specimen is received fresh labeled level 10 lymph node and consists of one fragment of tan-brown soft tissue measuring 1.2 cm in diameter. A small portion of the specimen is submitted for the [REDACTED]. The remainder of the specimen is submitted in toto.

B. The second specimen is received fresh labeled level 9 lymph node and consists of one fragment of tan-brown soft tissue measuring 0.6 cm in diameter. A small portion of the specimen is submitted for the [REDACTED]. The remainder of the specimen is submitted in toto.

C. The third specimen is received fresh labeled level 11 lymph node and consists of two fragments of dark brown soft tissue ranging in diameter from 0.2 up to 0.5 cm. The smaller fragment is submitted for the [REDACTED]. The larger fragment is submitted for permanent section.

D. The fourth specimen is received fresh labeled level 12 lymph node and consists of two fragments of tan-brown soft tissue measuring 5 mm in aggregate. A small portion of the specimen is submitted for the [REDACTED]. The remainder of the specimen is submitted in toto.

E. The fifth specimen is received fresh labeled level 14 lymph node and consists of multiple fragments of dark brown soft tissue measuring 1 x 0.8 x 0.5 cm. A small portion of the specimen is submitted for the [REDACTED]. The remainder of the specimen is submitted in toto.

F. The sixth specimen is received fresh labeled level 7 lymph node and consists of multiple fragments of tan-brown soft tissue measuring 1.5 x 1.2 x 0.5 cm in aggregate. A small portion of the specimen is submitted for the [REDACTED]. The remainder of the specimen is submitted in toto.

G. The seventh specimen is received fresh labeled R4 lymph node and consists of multiple fragments of tan-brown soft tissue measuring 2 x 1 x 0.5 cm in aggregate. A small portion of the specimen is submitted for the [REDACTED]. The remainder of the specimen is submitted in toto.

H. The eighth specimen is received fresh labeled R2 lymph node and consists of multiple fragments of dark brown soft tissue measuring 1.5 x 1.5 x 0.5 cm in aggregate. A small portion of the specimen is submitted for the [REDACTED]. The remainder of the specimen is submitted in toto.

[page 3 of 4]
Order Name:

Result Name:

Path Report

Observation Date-time:

Result Status:

Final Result

I. [redacted] reviewed the specimen and supervised the processing. The ninth specimen is received fresh labeled right middle lobe lung with en bloc wedge resection right upper lobe lung and consists of a lobectomy specimen measuring 1.5 x 2 x 4 cm. The bronchial and vascular margins are removed and submitted. Several metallic suture lines are present across the specimen. Sectioning the lung reveals a cystic mass measuring approximately 4.5 x 3.7 x 3.7 cm. The mass abuts the pleura, however, it does not grossly appear to involve the pleura. The tumor grossly infiltrates and partially encases the bronchus at the resection margin. The mass is slightly cystic appearing. Representative sections of the mass are submitted. A small portion of the mass is also submitted for the SPORE study. The remainder of the specimen consists of grossly unremarkable lung parenchyma. A representative section is submitted for the SPORE study and for permanent sections. The en bloc wedge resection from the upper lobe may represent one of the two suture lines across the specimen. Neither of the suture lines represents a measurable wedge resection.

3044

II. The tenth specimen is received fresh labeled tumor mass, pericardectomy and consists of one fragment of tan-brown soft tissue measuring 2 x 1.2 x 0.3 cm. The specimen is serially sectioned and submitted in toto. [redacted]

Sections:

A.	Level 10 lymph node, all
B.	Level 9 lymph node, all
C.	Level 11 lymph node, all
D.	Level 12 lymph node, all
E.	Level 13 lymph node, all
F.	Level 7 lymph node, all
G.	R4 lymph node, all
H.	R2 lymph node, all
I.	Bronchial and vascular margins
12. 17.	Mass
18. & 19.	Normal appearing lung
J.	Tumor mass, pericardectomy, all

MICROSCOPIC DESCRIPTION

Slides: 28 H & E, Immunohistochemical

Simultaneously performed controls verified the reliability of the staining procedure(s).

The specimens have been examined at multiple levels.

A. The first is a hyperplastic anthracotic lymph node. Metastatic carcinoma is not identified.

[page 4 of 4]
Data Date-Time

Order Name:

Result Name:

Path Report

Observation Date-time:

Result Status:

4 of 4

B. The second is a hyperplastic lymph node. Metastatic carcinoma is not identified.

C. The third is an anhracotic lymph node. Metastatic carcinoma is not identified.

D. The fourth is an anhracotic lymph node. Metastatic carcinoma is not identified.

E. The fifth is an anhracotic lymph node. Metastatic carcinoma is not identified.

F. The sixth is a hyperplastic anhracotic lymph node. Metastatic carcinoma is not identified.

G. The seventh is a hyperplastic anhracotic lymph node. Metastatic carcinoma is not identified.

H. The eighth is an anhracotic lymph node. Metastatic carcinoma is not identified.

I. The bronchial and vascular margins are free of carcinoma. A focus of carcinoma is present in the bronchial margin section, within adherent and adjacent pulmonary parenchyma. The tumor is composed of infiltrating cords and sheets of neoplastic cells having moderately pleomorphic and hyperchromatic nuclei. Local marked nuclear pleomorphism is present. Scattered mitoses are present averaging approximately 5 per 10 HPF's. Overt lymphovascular invasion is not identified. The mitotic rate is variable from approximately 5 to as many as 10 per 10 HPF's. Overt lymphovascular invasion is not identified. Immunohistochemical stains were previously performed on the biopsy, which were consistent with poorly differentiated adenocarcinoma showing positivity for CK7 and negative cytokeratin 20 staining. The TTF-1 was positive. Pleural infiltration is not identified. The surrounding pulmonary parenchyma does not exhibit obstructive pneumonia. Emphysematous change is present. The tumor is engulfing and partially obliterating bronchi.

J. The last portion of the specimen is dense fibrovascular tissue consistent with pericardium. A focus of adenocarcinoma is present within the pericardium. Further clinical correlation is necessary to establish if the tumor is from direct extension or metastasis. (END OF REPORT)

The immunohistochemical test(s) performed at [REDACTED], Department of Pathology may or may not be cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such

Source: NCI Genomic Data Commons file 183788fa-ec6d-47e0-89f0-e7c6f73283f0 (TCGA-49-6767.8E8171DC-1BAA-4B81-8E05-E15714135C1F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).